Gene-level copy-number profile of tumor specimen TCGA-EB-A4OY-01A from TCGA case TCGA-EB-A4OY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.1 years (23,771 days).
Specimen TCGA-EB-A4OY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8a809e19-d009-4432-a626-ddbed5cdf914.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A4OY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37bfb0e8-e02c-449d-b4bb-4cbc3d0c376d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 3,593; copy number 2: 17,864; copy number 3: 19,364; copy number 4: 13,637; copy number 5: 1,712; copy number 6: 1,726; copy number 7: 1,651; copy number 8: 24; copy number 9: 46; copy number 14: 40; copy number 21: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A4OY-01A-11D-A25P-01): tumor purity 0.58, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:142,286,917–142,518,983, 3 genes: RPL5P13, LSM3P4, AC139720.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,767 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:78,649,796–80,124,361, 13 genes, copy number 7: IFI44, AC104837.2, AC104837.1, ADGRL4, PSAT1P3, AL353651.2, AL353651.1, LINC02792, ADH5P2, AC099671.1, AC098657.1, AC098657.2, AC098657.3.
- chr1:84,363,706–85,600,734, 33 genes, copy number 7: UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1.
- chr1:231,626,790–232,041,272, 1 gene, copy number 7 (within-gene range 6–7): DISC1.
- chr1:231,767,464–236,065,109, 98 genes, copy number 7 (broad region; genes not listed).
- chr1:236,215,101–248,919,946, 290 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:12,583,601–12,673,883, 2 genes, copy number 14: RAF1, CRIP1P1.
- chr3:35,215,705–35,872,198, 6 genes, copy number 21: KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1.
- chr8:46,028,804–114,791,929, 1,027 genes, copy number 7 (broad region; genes not listed).
- chr8:117,794,490–127,742,951, 156 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:128,634,199–130,017,129, 18 genes, copy number 7: CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr8:130,069,541–130,163,127, 3 genes, copy number 7: RNU6-1255P, ASAP1-IT2, AC103725.1.
- chr8:135,859,369–138,914,041, 12 genes, copy number 8 (within-gene range 6–8): LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1.
- chr12:4,720,400–5,092,742, 12 genes, copy number 8 (within-gene range 6–8): GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3.
- chr12:11,158,785–12,568,776, 36 genes, copy number 7: AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1.
- chr12:67,351,436–68,332,381, 19 genes, copy number 7: MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1.
- chr12:68,344,664–68,349,959, 1 gene, copy number 7: AC022511.1.
- chr16:10,864,914–11,916,082, 38 genes, copy number 14 (within-gene range 2–14): AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3.
- chr19:31,348,881–31,417,794, 2 genes, copy number 7: AC025809.1, AC025809.2.

Autosomal genes at a single copy (total copy number 1): 2,274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
